Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8166, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8166-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med: Rec.: [REDACTED]

Phone Number: [REDACTED]

DOB: [REDACTED]

Gender: F

Client: [REDACTED]

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

CLINICAL HISTORY

[REDACTED] woman experienced recent onset seizures, and had a left frontal biopsy diagnosed as anaplastic astrocytoma. On imaging, there is a large ill-defined, diffusely infiltrating frontal lesion that involves the body of the corpus callosum and has faint blush with gadolinium.

OPERATIVE DIAGNOSES

Left frontal brain tumor

Operation/Specimen: A: Brain, left frontal mass, biopsy
B: Brain, contrast enhancing nodule, biopsy

PATHOLOGICAL DIAGNOSIS:

A, B. Brain, left frontal, excisional biopsies: Mixed oligoastrocytoma.

See Microscopy Description and Comment.

COMMENT

The sections contain portions of mostly white matter that is slightly (A1) to moderately infiltrated (B1) by a glial neoplastic proliferation. The neoplastic nuclei have mixed oligodendroglial and astrocytic features. There is one mitotic figure in all the sections examined. There is not microvascular cellular proliferation or necrosis.

In the sections from the [REDACTED] there is more cellular tumor, which has proclivity for the cerebral cortex and prominent microcystic changes; in a couple of sections [REDACTED] there is

[page 2 of 5]
cellular solid neoplasm.

The findings are interpreted as those of a diffusely infiltrating mixed oligoastrocytoma (WHO II). On this material there are no anaplastic features; increased cellularity and mitoses, although rare, may portend heightened biological potential.

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S1612, D19S412, PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

[page 3 of 5]
FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

[page 4 of 5]
stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, left frontal mass, biopsy:

1. TP: Atypical isolated nuclei, few, reactive astrocytes, and few perivascular lymphocytes, not diagnostic (compatible with infiltrating glioma, other). Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record.

2. FS: Rarefied white and grey matter, some reactive astrocytes, few atypical naked nuclei, perineuronal satellitosis, not diagnostic (R/O infiltrating glioma, other). More tissue, abnormal, for permanents will be submitted. [REDACTED] Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Left frontal brain mass," received fresh, two large fragments of brain tissue, mostly white matter; 2.3 x 1.7 x 0.9 cm in aggregate. In total, A1-A3.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates reactive plump astrocytosis, and a sparse gliofibrillary background. The CD153 depicts prominent

[page 5 of 5]
vascular-associated microglia, and absent activated/phagocytic forms.
With
the KP1 there are not phagocytic cells. With the p53 there is an
appreciable
population of large nuclei that strongly over express the protein.
The MIB-1
proliferation highlights several large cycling nuclei, probably
neoplastic.

ICD-9(s):
191.1 191.1

Histo Data

Part A: Brain, left frontal mass, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
H/E x 1	2		
H/E x 1	3		

Part B: Brain, contrast enhancing nodule, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
CD163 Vector x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
KP1-DA x 1	1		
LOH-curles x 1	1		
MGMT-curles x 1	1		
MIB1-DA x 1	1		
P53DO7 x 1	1		

*** End of Report ***

Source: NCI Genomic Data Commons file aa8b720b-c9f9-445c-a777-2828c837e4a7 (TCGA-DU-8166.D4140F71-F42D-4B23-BFF6-9F0C00A7E6FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).